Surgical pathology report (de-identified scan), TCGA case TCGA-OY-A56P, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of North Carolina, specimen TCGA-OY-A56P-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

Adenocarcinoma, papillary
Serous 846013

Site: R Ovary, C56.9
12/4/12 J

Diagnosis:

A: Ovary and fallopian tube, right, salpingo-oophorectomy

Histologic type: Ovarian papillary serous adenocarcinoma with associated psammoma bodies, 17 cm in greatest dimension (see comment)

Histologic grade: High grade (grade 3)

Ovarian surface involvement: Present

Fallopian tube:

- Surface of fallopian tube involved by serous adenocarcinoma

Lymph nodes: Not applicable

Other findings: Ovary with hemorrhagic corpus luteum

B: Ovary and fallopian tube, left, salpingo-oophorectomy

- High grade papillary serous adenocarcinoma, 7 cm in greatest dimension
- No ovarian surface involvement identified
- Fallopian tube with no specific pathologic abnormality

C: Peritoneum, pelvic, biopsy

- Involved by serous adenocarcinoma, largest implant 1.5 cm in greatest dimension

D: Omentum, omentectomy

- Involved by serous adenocarcinoma, largest implant 1 cm in greatest dimension

AJCC PATHOLOGIC TNM STAGE: pT3b pNx

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

A couple of foci were suspicious for lymphovascular space invasion. However, immunostains for CD31 and CD34 were performed on blocks A1 and A8, and no intravascular tumor is identified. Therefore, no lymphovascular space invasion is identified.

[page 2 of 4]
Intraoperative Consult Diagnosis:
Frozen section was requested by

FSA1: Ovary, right, oophorectomy
- Adenocarcinoma, favor ovarian primary serous adenocarcinoma
(CEA negative, elevated CA125).
- Surface involvement present (sampled with one of the sections)

Clinical History:
-year-old with adnexal mass.

Gross Description:
Specimen A is received in one appropriately labeled container.
The specimen was received fresh for frozen section and placed in formalin.

Specimen fixation: Fresh for frozen section and then placed in formalin.

Type of specimen: Salpingo-oophorectomy, ruptured

Tumor site: Right with questionable surface involvement

Ovarian surface: Purple/red, focally nodular with adhesions and is disrupted. Attached to the surface is a 6.4 x 4.3 x 1.5 cm portion of fibrofatty tissue with embedded blood clot consistent with omentum. Embedded on the ovarian surface is a 4.5 cm long and up to 1.0 cm in diameter edematous fallopian tube with fimbria not grossly identified. The mucosa is pink/tan and is grossly uninvolved by mass.

Ovary/tumor size: 440 grams, 17.0 x 9.0 x 8.0 cm, which replaces the ovary with the exception of a 1.0 x 0.4 x 0.2 cm hemorrhagic corpus luteum.

Description of tumor: The tumor consists of a complex ovarian mass with cystic and solid components, mostly solid, tan mucoid areas and polypoid areas suspicious for surface involvement. A portion of the tumor was frozen as representative FSA1.

Digital Picture: No

[page 3 of 4]
Myometrium:

thickness of wall: 1.2 cm

other findings: The right adnexa shows a yellow/tan mass which appears to invade into the right myometrium. This has a fibrous pseudocapsule surrounding it. Cut section demonstrates yellow/tan, solid and papilliferous surface with central hemorrhage.

Sectioning of the myometrium demonstrates tumor throughout the myometrium extending to the left adnexa and involving the left ovary with a similar white/tan, firm lobular to papilliferous mass. Tumor involves 1.8 cm of 2.0 cm of myometrium grossly. The tumor is adjacent to the blue inked surgical margin.

Adnexa:

Right ovary:

measurement: 5.6 x 3.0 x 2.0 cm

external surface: lobulated, irregular and is adherent to the right fundic region cut surface: --

Right fallopian tube:

Other findings: Cannot definitely be identified in this mass; the ligament on the right is free of tumor. There was an additional separate piece of adnexal structure which appears to be a fallopian tube with a fimbriated end. This measures 9.5 x 0.9 cm and may have been part of the left adnexal mass and not likely right adnexal region.

Left ovary:

measurement: 4.0 x 3.1 x 1.8 cm

external surface: lobulated and irregular

cut surface: demonstrates white/tan firm to papilliferous mass involving the ovarian parenchyma

Left fallopian tube:

measurement: 4.5 x 0.7 cm

other findings: The left fallopian tube also appears to be involved with this mass.

Other comments: none

Tissue submitted for special investigations: no

Block Summary:

(Inking: posterior side=black, anterior side=blue; the mass detached from the specimen which appears to be from the top of the uterine fundus was inked green over the area sampled)

[page 4 of 4]
A1 - anterior cervix
A2 - posterior cervix
A3 - anterior corpus with adjacent left adnexa
A4,A5 - anterior corpus and adjacent left adnexa
A6 - posterior corpus and adjacent right adnexal invading mass
A7-A10 - anterior corpus, quadrisected from right to left including portions of ovary/adnexal structures
A11,A12 - right ovary, bisected
A13,A14 - left ovary, bisected
A15 - section of mass received detached from main specimen and used per FSA1
A16,A17 - central section of detached mass, bisected
A18 - possible fallopian tube of left adnexa, part of detached mass
A19 - fimbriated end of A18
A20,A21 - fallopian tube and fimbriated end, ?right adnexa found separate/detached in Specimen A

Container B holds a 21.5 x 14.5 x 4.5 cm omentum. A portion is soft, yellow/tan with fibroadipose tissue. Within this are areas of firm white adherent masses, the largest 10.5 x 7.5 x 3.5 cm. A smaller satellite mass, 6.0 x 3.2 x 2.4 cm is identified. Sectioning demonstrates white to tan firm mass with central areas of necrosis.

Block Summary:

B1 - representative section of smaller mass
B2-B4 - representative section of largest mass, trisected
B5 - additional representative section of largest mass
B6 - additional section of smaller omental mass

Case is Synchronous		

12/5/12

Source: NCI Genomic Data Commons file ad1340ea-2b76-4a60-97c0-b2ec354fab2f (TCGA-OY-A56P.D916ED58-54D5-43FC-A5B0-6E4844A7F677.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).